Gene-level copy-number profile of tumor specimen TCGA-A7-A0CE-01A from TCGA case TCGA-A7-A0CE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.1 years (20,863 days).
Specimen TCGA-A7-A0CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.f79ed0dc-7704-4967-b62c-0112de377fc3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0CE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4dd36f3d-f6e4-4be0-b08d-97b87c4c596b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 3,501; copy number 2: 17,430; copy number 3: 27,269; copy number 4: 7,828; copy number 5: 2,356; copy number 6: 1,268; copy number 8: 133.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A0CE-01A-11D-A011-01): tumor purity 0.73, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr13:31,199,975–32,538,885, 20 genes: B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,389,567–48,711,226, 8 genes (within-gene range 0–1): LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 133 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,327,068–191,228,467, 133 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,986. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
